CPTAC case C3N-02422 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dd2d4fc9-3422-4548-85fe-43e5b8da5ed3

Demographics
Sex at birth: female; Race: asian; Year of birth: 1961; Vital status: Dead; Days to death: 650 days (1.8 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: China.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 56.3 years (20,562 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M1b; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IV; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 650 days (1.8 years); Progression or recurrence: yes; Days to last follow up: 552 days (1.5 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.8 cm; Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 14; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 362 days; Disease response: With Tumor; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 552 days (1.5 years); Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 552 days (1.5 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 118 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 65 kg; Height: 161 cm; BMI: 25.08; DLCO (% of predicted): 96; FEV1/FVC before bronchodilator (%): 87; FEV1 before bronchodilator (% of reference): 76.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (9 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02422-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 100 mg; Time between clamping and freezing: 35 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02422-21: Section location: Right Upper Lobe; Percent tumor nuclei: 80; Percent necrosis: 2.
- Sample C3N-02422-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 100 mg; Time between clamping and freezing: 35 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02422-22: Section location: Right Upper Lobe; Percent tumor nuclei: 70; Percent necrosis: 2.
- Sample C3N-02422-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 100 mg.
- Samples C3N-02422-31, C3N-02422-32, C3N-02422-72, C3N-02422-73, C3N-02422-74 (5 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-02422-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -3 days; Method of sample procurement: Blood Draw.
